Somatic mutation profile of tumor specimen TARGET-10-PATZWA-03A (aliquot TARGET-10-PATZWA-03A-01D) from TARGET case TARGET-10-PATZWA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.1 years (3,686 days).
Specimen TARGET-10-PATZWA-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4dc553e-e3eb-4075-ae84-6d2ac24e4dc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATZWA-10A (Blood Derived Normal), aliquot TARGET-10-PATZWA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92bd29b3-ab97-4bf5-9136-5b586af10454

The open-access MAF lists 45 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 12, Frame Shift Ins 4, Intron 3, Nonsense Mutation 1, Frame Shift Del 1, 3'UTR 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK3 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs758959409, COSV71685371; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.1861G>T p.E621* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV62788706; called by muse, mutect2, varscan2
- ARHGAP10 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs764534458, COSV60594350; called by muse, mutect2, varscan2
- CCDC116 | c.131G>C p.R44P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.209); catalogued as rs148804210, COSV53037087; called by muse, mutect2, varscan2
- CTNNA2 | c.988A>T p.R330W | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63545010; called by muse, mutect2, varscan2
- DIAPH2 | c.2617A>G p.K873E | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV61259627; called by muse, varscan2
- DNAH11 | c.6478C>A p.L2160I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60938172; called by muse, mutect2, varscan2
- DNAH9 | c.7705G>T p.D2569Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52332590; called by muse, mutect2, varscan2
- HHIPL1 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs1344617006, COSV58088978; called by muse, mutect2, varscan2
- HTR2C | c.350A>T p.D117V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52200929; called by muse, mutect2, varscan2
- JAK1 | c.2514C>A p.F838L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61086903; called by muse, mutect2, varscan2
- LARP1 | c.2827G>A p.A943T (on ENST00000518297 / NM_033551.3; = p.A866T on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV60424375; called by muse, mutect2, varscan2
- MYB | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57195864; called by muse, mutect2, varscan2
- MYLK4 | c.796A>T p.T266S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51138144, COSV51148088; called by muse, mutect2, varscan2
- NOTCH1 | c.7375del p.Q2459Rfs*18 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as COSV53025731; called by mutect2, pindel, varscan2
- NOTCH1 | c.5101G>C p.A1701P | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53026331, COSV99072404; called by muse, mutect2
- OR2G3 | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV60680725; called by muse, mutect2, varscan2
- OR52J3 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.928); catalogued as COSV66746299; called by muse, mutect2, varscan2
- PDGFRB | c.1621C>A p.L541M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55800389; called by muse, mutect2, varscan2
- PITPNM1 | c.2228T>C p.L743P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470035212; called by muse, mutect2
- STAG2 | c.288+1G>A p.X96_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as rs767025385, COSV54350347, COSV54356586, COSV54369950; called by muse, mutect2, varscan2
- TENM1 | c.7444C>A p.L2482I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV64424495; called by muse, mutect2, varscan2
- ZNF292 | c.3470dup p.L1157Ffs*64 | Frame Shift Ins (INS) | VAF 20/66 reads (30%) | catalogued as rs1306238628; called by mutect2, pindel, varscan2
- ARHGEF10 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IGHD6-19 | c.1_4delinsTGCAGTTCGTACGCC p.G1Cfs*? | Frame Shift Ins (INS) | VAF 30/90 reads (33%) | called by pindel, varscan2*
- KMT2A | c.9304dup p.I3102Nfs*8 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- PTPRC | c.1379dup p.H460Qfs*11 | Frame Shift Ins (INS) | VAF 7/33 reads (21%) | called by mutect2, pindel
- RUFY4 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.052); called by muse, mutect2
- ARHGEF9 | c.525C>T p.P175= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- ASTN1 | c.630C>T p.G210= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV56064658; called by muse, mutect2, varscan2
- CRMP1 | c.1443C>T p.R481= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs143852988, COSV61480762; called by muse, mutect2, varscan2
- DSCAML1 | c.3495C>T p.D1165= (on ENST00000321322; = p.D1105= on NM_020693.4) | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs753645055, COSV100357530; called by muse, mutect2, varscan2
- HECW1 | c.2661C>T p.N887= | Silent (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- IGSF9 | c.2493G>A p.P831= (on ENST00000368094 / NM_001135050.2; = p.P815= on NM_020789.4) | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV57422107; called by muse, mutect2, varscan2
- MEAK7 | c.1230G>A p.A410= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs776161259, COSV59144882; called by muse, mutect2, varscan2
- OTUD7A | c.501C>T p.I167= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as rs781738212; called by muse, mutect2, varscan2
- PLA2G5 | c.333C>T p.D111= | Silent (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- POU3F4 | c.558G>A p.E186= | Silent (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- TBC1D16 | c.1689C>T p.F563= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs547144215, COSV60479718; called by muse, mutect2, varscan2
- ZKSCAN8 | c.216A>G p.L72= | Silent (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- COPB1 | c.2646+86G>A | Intron (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- HECTD4 | c.11926+63C>T | Intron (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2
- MIR663A | chr20:26208321 C>T | 5'Flank (SNP) | VAF 15/44 reads (34%) | catalogued as rs760501521; called by muse, mutect2, varscan2
- RPS4X | c.361-100dup | Intron (INS) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- TSPOAP1 | c.*56G>T | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
